Gene-level copy-number profile of tumor specimen TCGA-UF-A7JK-01A from TCGA case TCGA-UF-A7JK, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.4 years (21,696 days).
Specimen TCGA-UF-A7JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.bb6539c9-ae7e-493b-ab9a-f8fb2b0859a2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UF-A7JK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d4021eab-47ec-4fe0-8236-493690822d30

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,366; copy number 2: 16,653; copy number 3: 24,321; copy number 4: 11,333; copy number 5: 5,049; copy number 6: 20; copy number 7: 855; copy number 8: 18; copy number 9: 44; copy number 11: 11; copy number 19: 25; copy number 23: 13; copy number 24: 38; copy number 26: 15; copy number 31: 12; copy number 40: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UF-A7JK-01A-11D-A34I-01): tumor purity 0.61, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,701,579–186,900,838, 4 genes: AC107050.1, AC108865.1, AC108865.2, MRPS36P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,068 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:134,437,605–184,457,891, 789 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr7:28,995,235–29,195,451, 1 gene, copy number 7 (within-gene range 6–7): CPVL.
- chr7:29,122,274–30,367,689, 30 genes, copy number 7 (within-gene range 4–7): AC005232.1, AC004593.2, CHN2, AC004593.1, CHN2-AS1, NANOGP4, AC007255.1, GTF3C6P3, PRR15, ZNRF2P2, TMSB4XP3, DPY19L2P3, MIR550A3, WIPF3, AC004912.1, SCRN1, FKBP14-AS1, FKBP14, PLEKHA8, AC007285.1, AC007036.4, AC007036.5, MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1.
- chr7:49,760,897–56,882,146, 140 genes, copy number 7–40 (broad region; genes not listed).
- chr10:3,991,160–4,515,244, 9 genes, copy number 11: MIR6078, AC025822.1, AC025822.2, LINC00702, LINC00703, AC022535.1, AC022535.3, AC022535.2, RNU6-163P.
- chr12:33,374,238–34,249,958, 18 genes, copy number 8: SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr13:71,437,966–77,662,626, 80 genes, copy number 9–31 (within-gene range 5–31) (broad region; genes not listed).
- chr13:77,698,012–77,698,116, 1 gene, copy number 9: MIR3665.

Autosomal genes at a single copy (total copy number 1): 1,278. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
